Surgical pathology report (de-identified scan), TCGA case TCGA-38-4626, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site UNC, specimen TCGA-38-4626-01A (Primary Tumor).

[page 1 of 2]
agnosis:

- Lung, left upper lobe, lobectomy.
- Adenocarcinoma, poorly differentiated, 5.3 cm diameter, bronchial and pleural margins not involved.
- Lymph nodes, peribronchial - No metastatic carcinoma identified (0/8).

B: Lymph nodes, station 5, removal.
- No metastatic carcinoma identified (0/2).

C: Lymph nodes, L10, removal.
- No metastatic carcinoma identified (0/2).

D: Lymph nodes, station 11, removal.
- No metastatic carcinoma identified (0/2).

Comment:
None.

Intraoperative Consultation: Frozen section is requested by Dr.

FSAl: Lung, left upper lobe, lobectomy, bronchial margin, biopsy
- No tumor seen in bronchial margin
- Two lymph nodes, no tumor seen (0/2)

Clinical History:
with adenocarcinoma of the left upper lobe of the lung.

Gross Description:
Received are four appropriately containers.

Container A:
Specimen fixation: formalin

Type of specimen/parts of lung received: left upper lobe lobectomy

Size of specimen: 17.5 x 11.0 x 5.8 cm

Weight of specimen: 340 g

Other attached structures: none

Tumor location: left upper lobe superior segment

Tumor size: 5.3 x 5.0 x 5.0 cm. Sectioning of the tumor reveals a firm, tan, slightly whorled, solid mass with pushing of regular borders which is somewhat circumscribed. The specimen almost has a cauliflower appearance.

Relationship of tumor to bronchus: Tumor does not grossly appear to be involving the bronchus.

Distance of tumor to bronchial margin: 1.1 cm

Relationship/distance of tumor to pleura: closest distance is 0.4 cm

Distance of tumor to other surgical margins: 1.1 cm from bronchial margin; tumor is 1.4 cm away from stapled surgical margin

Presence/absence of satellite tumor nodules: absent

Involvement of attached structures by tumor: no attached structures present

Description of nontumorous lung: remaining lung is red/tan and diffusely aerated. There are focal areas which appear consolidated.

Tissue submitted for special studies: yes, next section of bronchial margin, a representative section of tumor and representative section of normal lung parenchyma

Block Summary:

- JA1 - bronchial margin
- A1 - stapled surgical margin
- A2 - representative section of tumor at pleura
- A3 - representative section of tumor at pleura
- A4 - representative section of tumor and adjacent uninvolved lung
- A5 - representative section of tumor

[page 2 of 2]
A6 - representative section of uninvolved lung, inferior segment
A7 - two lymph node candidates
A8 - one lymph node candidate
A9 - representative section of tumor to distance of bronchus

Container B is additionally labeled "station 5". Within the container are two fragments of soft tissue which measure 1.5 x 1.8 x 0.4 cm in aggregate. The specimens are tan/brown and consistent with lymph nodes.

B1 - one lymph node candidate, bisected

B2 - one lymph node candidate, bisected, [REDACTED]

Container C is additionally labeled "L10". Within the container is a 1.5 x 0.5 x 0.4 cm, single, tan, irregular soft tissue fragment consistent with lymph node.

C1 - one lymph node candidate, bisected, [REDACTED]

Container D is additionally labeled "station 11". Within the container is a 0.5 x 0.5 x 0.3 cm, red/tan tissue fragment consistent with lymph node. The specimen is bisected in D1 [REDACTED].

Light Microscopy:

Light microscopic examination is performed by Dr.

The frozen section diagnosis is confirmed.

Tumor histologic type (WHO classification): adenocarcinoma

Tumor histologic grade (WHO classification): poorly differentiated

Tumor size (greatest dimension): 5.3 cm

Histologic assessment of surgical margins: not involved

Pleural involvement: not identified

In situ carcinoma: not identified

Invasion:

Angiolymphatic - not identified

perineural - not identified

Lymph nodes (by node group): 0/8 peribronchial 0/2 station 5 0/1 L10 0/1 station 11

Extracapsular extension of tumor in lymph nodes: n/a

Findings in nontumorous lung: hemosiderin-laden macrophages and post-obstructive changes

Source: NCI Genomic Data Commons file 7e22eb2e-6ec4-4a23-821f-95909061f6bd (TCGA-38-4626.9AC3C8F7-8399-46B1-9F2C-4E994FAF88A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).